TARGET case TARGET-30-PARLMK — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9b4b6830-67de-53dc-baa3-586477ac9dc5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 376 days (1.0 years).

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 4.4 years (1,597 days); Year of diagnosis: 2007; Days to last follow up: 376 days (1.0 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Necrosis percent: 0; Percent tumor nuclei: 85.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ANBL0421.
   Treatment given: Protocol identifier: ACCL05C1.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (3 entries)
- Days to follow up: 263 days; Progression or recurrence anatomic site: Bone marrow; Days to first event: 263 days; First event: Relapse.
- Days to follow up: 263 days; Progression or recurrence anatomic site: Bone, NOS.
- Days to follow up: 376 days (1.0 years); Year of follow up: 2008.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PARLMK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-30-PARLMK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 376
- Protocol: ANBL00B1, ACCL05C1, ANBL0032, ANBL0421
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.05
- Histology: Unfavorable
- MKI: Low
- Diagnostic Category: Ganglioneuroblastoma, nodular
- ICDO Description: Retroperitoneum Periadrenal tissue Perinephric tissue Peripancreatic tissue Perirenal tissue Retrocecal tissue Retroperitoneal tissue
- Percent Necrosis: 0
- Percent Tumor v/s Stroma: 85/15
- Site of Relapse: Primary Site; Bone; Bone Marrow
